CGCI case BLGSP-71-30-00680 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fea7e19c-5b99-4ac1-9cb7-317444aafa2e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 28 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: primary; Age at diagnosis: 28.1 years (10,248 days); Year of diagnosis: 2006; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage I; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 917 days (2.5 years); Ann Arbor extranodal involvement: No; Burkitt lymphoma clinical variant: Immunodeficiency-associated, adult; Max tumor bulk site: Axillary lymph nodes.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Axillary; Lymph nodes positive: 1; Lymph nodes tested: 1; Tumor largest dimension diameter: 8 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-IVAC; Days to treatment start: 22 days; Days to treatment end: 142 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CODOX-M; Days to treatment start: 22 days; Days to treatment end: 142 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Methotrexate + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 22 days; Days to treatment end: 142 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 1.
- Days to follow up: 917 days (2.5 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day -1,337.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- MIB1 (IHC): Positive.
- MYC translocation (FISH): Abnormal, NOS.
- Lactate Dehydrogenase 469 [Blood test normal range upper: 618].

Other clinical attributes
- Day -1,337: Risk factors: HIV/AIDS.
- Day -1,337: Comorbidities: HIV/AIDS.
- Day 0: Weight: 93 kg; Height: 186 cm; BMI: 26.9; CD4 count: 570; Haart treatment indicator: Yes; HIV viral load: 13600.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Comorbidities: Human Papillomavirus Infection.
- Day 917: Nadir CD4 count: 380.

Biospecimens (2 samples)
- Sample BLGSP-71-30-00680-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: FFPE; Days to sample procurement: 0 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00680-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: Yes; New tumor event diagnosis indicator: No.
- History of disease: Haart therapy prior to diagnosis: No; Haart therapy at diagnosis: Yes; Cdc HIV risk group: Homosexual or bisexual contact.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Lymph nodes examined: Yes.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 469; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: MIB-1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CODOXMR/IVACR (Magrath protocol); Pharma adjuvant cycles count: 4.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00680-01A-01E-0001-01:
- % tumour: 95
